Somatic mutation profile of tumor specimen TCGA-VP-A87E-01A (aliquot TCGA-VP-A87E-01A-31D-A34U-08) from TCGA case TCGA-VP-A87E, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.7 years (21,811 days).
Specimen TCGA-VP-A87E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d3b3ea1-7a00-4ad4-ae04-2377d4f45b40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87E-10A (Blood Derived Normal), aliquot TCGA-VP-A87E-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8f4c79e-3247-47d0-a0bb-2336af52d285

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP11 | c.2387C>A p.S796Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99214480; called by muse, mutect2
- AP2B1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs1473787168, COSV99251850; called by muse, mutect2
- AP2B1 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99251852; called by muse, mutect2
- ARSD | c.404T>G p.I135S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV99472481; called by mutect2, varscan2
- GRM1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763886921, COSV51110227; called by muse, mutect2, varscan2
- HHAT | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99806112; called by muse, mutect2, varscan2
- MAMLD1 | c.1607C>G p.P536R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476707; called by muse, mutect2, varscan2
- MATN2 | c.1706T>G p.V569G | Missense Mutation (SNP) | VAF 10/305 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV99647384; called by muse, mutect2
- MLH3 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53154897; called by muse, mutect2
- PUDP | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs778192547, COSV66903665; called by muse, mutect2
- SMC1A | c.1525C>G p.R509G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100447745, COSV59128902; called by muse, mutect2, varscan2
- ZNF18 | c.1541A>G p.H514R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100503211; called by muse, mutect2
- GPNMB | c.54A>C p.P18= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV99326925; called by muse, mutect2
- LGSN | c.1437C>T p.T479= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as rs1397677250, COSV65728250; called by muse, mutect2
- STAG2 | c.525T>C p.F175= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV99495827; called by muse, mutect2, varscan2
- MAPK1IP1L | c.-108G>A | 5'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as rs1255957447; called by muse, mutect2
- PPP1R9A | c.2757+569T>C | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs1342160315, COSV99198417; called by muse, mutect2, varscan2
